Somatic mutation profile of tumor specimen TCGA-AO-A12D-01A (aliquot TCGA-AO-A12D-01A-11D-A10Y-09) from TCGA case TCGA-AO-A12D, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 43.2 years (15,774 days).
Specimen TCGA-AO-A12D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d817444-8b40-4d79-9698-8539c58fe0f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AO-A12D-10A (Blood Derived Normal), aliquot TCGA-AO-A12D-10A-01D-A110-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cce3fe79-e88b-4448-ace1-ee973ff72478

The open-access MAF lists 58 somatic variants for this specimen: 42 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 14, Nonsense Mutation 2, Intron 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT2 | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51488811; called by muse, mutect2, varscan2
- BEND3 | c.2167G>A p.D723N | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV64681820, COSV64682090; called by muse, mutect2, varscan2
- CACNA2D1 | c.845C>T p.T282I | Missense Mutation (SNP) | VAF 15/177 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100667347; called by muse, mutect2
- CHAMP1 | c.1729G>C p.E577Q | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.315); catalogued as COSV63522781, COSV63523423; called by muse, mutect2
- CUX2 | c.4007C>T p.P1336L | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs372685449, COSV55641719; called by muse, mutect2, varscan2
- DCAF12 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as COSV63513307; called by muse, mutect2, varscan2
- DMAC2 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99700717; called by muse, mutect2, varscan2
- EXOC4 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs183280115, COSV54081769, COSV99555488; called by muse, mutect2, varscan2
- GBP5 | c.490G>C p.E164Q | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.131); catalogued as COSV58593789; called by muse, mutect2, varscan2
- GFM1 | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51834620; called by muse, mutect2, varscan2
- KAT6B | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.572); catalogued as rs761606204, COSV54751817; called by muse, mutect2, varscan2
- KCNJ12 | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.45); catalogued as COSV59164166; called by muse, mutect2
- KIF4B | c.2319C>G p.I773M | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs377351058; called by muse, mutect2
- LHX5 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.768); catalogued as COSV55664638, COSV99922559; called by muse, mutect2
- MUC16 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.427); catalogued as COSV101201746; called by muse, mutect2
- NYAP1 | c.1990C>T p.P664S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as COSV55720809; called by muse, mutect2, varscan2
- OR2B11 | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 44/207 reads (21%) | catalogued as rs145019591; called by muse, mutect2, varscan2
- PCDHA5 | c.2017C>A p.Q673K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.022); catalogued as COSV65355241; called by muse, mutect2, varscan2
- PCNT | c.4954G>A p.E1652K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); catalogued as rs766015045, COSV100854973; called by muse, mutect2
- PDGFRA | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57271411; called by muse, mutect2, varscan2
- PLCG1 | c.3358G>A p.E1120K | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as COSV54821626; called by muse, mutect2, varscan2
- PRAMEF17 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs76434036; called by muse, mutect2, varscan2
- PTPRH | c.824G>T p.C275F | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99671464; called by muse, mutect2
- SEC31B | c.2431G>C p.E811Q | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV64845188; called by muse, mutect2, varscan2
- SLCO5A1 | c.1980C>A p.F660L | Missense Mutation (SNP) | VAF 38/362 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV52664341, COSV52666112; called by muse, mutect2
- SMYD5 | c.1022T>G p.I341S | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99240367; called by muse, mutect2
- SNAPC1 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV99359427; called by muse, mutect2
- SPRTN | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs145727605, COSV99149514; called by muse, mutect2
- STUB1 | c.239T>C p.L80P | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.905); catalogued as COSV99556012; called by muse, mutect2
- TENM1 | c.6244G>A p.V2082I | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); catalogued as COSV64438557; called by muse, mutect2, varscan2
- TGFBR1 | c.683A>T p.E228V | Missense Mutation (SNP) | VAF 56/308 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as CD086260, COSV66626415; called by muse, mutect2, varscan2
- THAP12 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as COSV52611872; called by muse, mutect2, varscan2
- TP53 | c.723del p.C242Afs*5 | Frame Shift Del (DEL) | VAF 23/80 reads (29%) | catalogued as COSV53025058, COSV53153033, COSV53211006; called by mutect2, pindel, varscan2
- TPO | c.2278G>A p.G760R | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV61107364; called by muse, mutect2, varscan2
- UPK2 | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.657); catalogued as COSV50629270, COSV99875130; called by muse, mutect2, varscan2
- VPS33A | c.1777G>C p.E593Q | Missense Mutation (SNP) | VAF 29/239 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV57358224; called by muse, mutect2, varscan2
- VSIG8 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 7/82 reads (9%) | catalogued as rs1165205660, COSV63652289; called by muse, mutect2
- XRN2 | c.1844G>A p.R615Q | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as rs376273044; called by muse, mutect2, varscan2
- ZBBX | c.1970G>T p.R657L | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.185); catalogued as COSV56781862, COSV56784614; called by muse, mutect2
- ZNF157 | c.237G>C p.L79F | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.888); catalogued as COSV65659398; called by muse, mutect2, varscan2
- ZNF41 | c.2113C>T p.R705C | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.764); catalogued as rs771347084, COSV57444460; called by muse, mutect2, varscan2
- ZW10 | c.1250C>T p.S417L | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV99562909; called by muse, mutect2, varscan2
- BOD1L1 | c.2586C>T p.I862= | Silent (SNP) | VAF 37/245 reads (15%) | catalogued as rs771299954, COSV50034445; called by muse, mutect2, varscan2
- CADM1 | c.681C>T p.V227= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV100523417; called by muse, mutect2, varscan2
- CD200 | c.609G>A p.G203= (on ENST00000473539 / NM_001004196.3; = p.G178= on NM_005944.7 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 21/216 reads (10%) | catalogued as rs371629783; called by muse, mutect2, varscan2
- CYP2C19 | c.411G>A p.G137= | Silent (SNP) | VAF 60/363 reads (17%) | catalogued as COSV100990633; called by muse, mutect2, varscan2
- CYTH3 | c.591C>T p.I197= | Silent (SNP) | VAF 18/178 reads (10%) | catalogued as rs750567643, COSV63440290; called by muse, mutect2, varscan2
- DDX10 | c.567C>T p.N189= | Silent (SNP) | VAF 7/94 reads (7%) | catalogued as COSV100489955; called by muse, mutect2
- FPGT-TNNI3K | c.1644G>A p.K548= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as COSV100438086; called by muse, mutect2
- FXR1 | c.1407C>G p.L469= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as COSV59764894; called by muse, mutect2, varscan2
- GJA10 | c.90C>T p.F30= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as COSV101005449; called by muse, mutect2
- GLRB | c.849C>T p.L283= | Silent (SNP) | VAF 24/168 reads (14%) | catalogued as COSV52420206; called by muse, mutect2, varscan2
- HIVEP2 | c.4398C>T p.Y1466= | Silent (SNP) | VAF 41/235 reads (17%) | catalogued as rs762453316, COSV50007838; ClinVar: likely benign; called by muse, mutect2, varscan2
- NFIA | c.360C>T p.L120= | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as COSV64535667; called by muse, mutect2
- PSME3IP1 | c.732C>T p.I244= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV58430026; called by muse, mutect2, varscan2
- TRIM55 | c.312C>A p.I104= | Silent (SNP) | VAF 17/155 reads (11%) | catalogued as COSV52548946, COSV52550488; called by muse, mutect2, varscan2
- ANKRD13D | c.*527G>A | 3'UTR (SNP) | VAF 5/72 reads (7%) | catalogued as COSV100398628; called by muse, mutect2
- EPHA6 | c.1895-8927C>G | Intron (SNP) | VAF 19/185 reads (10%) | catalogued as COSV67585466; called by muse, mutect2, varscan2
